CCDI case PBCDUV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/b3c3c40f-9916-4c70-9214-e989c5627f34

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 0.4 years (162 days).

Biospecimens (3 samples)
- Sample 0DPQQB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DPQQG, 0DPQQM (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
